Somatic mutation profile of cancer-model specimen HCM-CSHL-0238-C18-85A (3D Organoid; aliquot HCM-CSHL-0238-C18-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0238-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.8 years (26,209 days).
Specimen HCM-CSHL-0238-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c10a2cd3-dc68-4c38-8150-8719df50d05c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0238-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0238-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c60722d2-eacb-4049-bf0f-2cf3f44ef55d

The open-access MAF lists 156 somatic variants for this specimen: 103 protein-altering or splice-affecting, 39 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 39, Nonsense Mutation 8, Frame Shift Del 6, RNA 5, Intron 4, Splice Region 3, 3'UTR 2, 5'UTR 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 52/174 reads (30%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 87/274 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1382G>A p.R461Q (on ENST00000404938 / NM_001163941.2; = p.R16Q on NM_178559.6) | Missense Mutation (SNP) | VAF 170/298 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs201067658; called by muse, mutect2, varscan2
- ABCE1 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV56847690; called by muse, mutect2, varscan2
- ACTN2 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 119/394 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs201335965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BPIFB1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 272/513 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs200607499, COSV53604972; called by muse, mutect2, varscan2
- CCDC138 | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs754140438; called by muse, mutect2, varscan2
- CCDC180 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 107/173 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs755611545; called by muse, mutect2, varscan2
- CDK14 | c.430G>A p.G144R (on ENST00000380050 / NM_001287135.2; = p.G126R on NM_012395.3) | Missense Mutation (SNP) | VAF 146/196 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56043685; called by muse, mutect2, varscan2
- CTSG | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 93/213 reads (44%) | catalogued as rs752353482, COSV99361305; called by muse, mutect2, varscan2
- EHD3 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); catalogued as rs767841259; called by muse, mutect2, varscan2
- FBXL7 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 101/327 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as rs1311959635, COSV61654808; called by muse, mutect2, varscan2
- FCRLA | c.164C>T p.T55M (on ENST00000367959; = p.T32M on NM_032738.4) | Missense Mutation (SNP) | VAF 120/474 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs753826864, COSV52686120; called by muse, mutect2, varscan2
- FREM2 | c.4439C>T p.T1480M | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs773471950, COSV54827280; called by muse, mutect2, varscan2
- HDAC9 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs370076387; called by muse, mutect2, varscan2
- HDX | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 175/175 reads (100%) | catalogued as rs1233675238, COSV52977081; called by muse, mutect2, varscan2
- HECTD4 | c.12094C>A p.Q4032K | Missense Mutation (SNP) | VAF 122/324 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs781129768; called by muse, mutect2, varscan2
- HECW1 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs201521619, COSV67837133; called by muse, mutect2, varscan2
- HERC2 | c.9149T>C p.V3050A | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28439160; called by muse, mutect2, varscan2
- HIP1R | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773294717, COSV53440381; called by muse, mutect2, varscan2
- KHDRBS2 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 110/189 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs17853264, COSV55456305; called by muse, mutect2, varscan2
- KLHL30 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 103/155 reads (66%) | SIFT tolerated (0.51); PolyPhen benign (0.37); catalogued as rs1264620780; called by muse, mutect2, varscan2
- LAMC3 | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 114/177 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs200194697, COSV62655252; called by muse, mutect2, varscan2
- LCT | c.908-7C>G | Splice Region (SNP) | VAF 60/244 reads (25%) | catalogued as COSV99929315; called by muse, varscan2
- LILRA1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs771954481, COSV99251925; called by muse, mutect2, varscan2
- LRP1B | c.12878G>T p.C4293F | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67269295; called by muse, mutect2, varscan2
- MGAM | c.4015G>A p.V1339I | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.552); catalogued as rs745975997, COSV72075184; called by muse, mutect2, varscan2
- MVK | c.836T>A p.L279Q | Missense Mutation (SNP) | VAF 175/516 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM128661; called by muse, mutect2, varscan2
- NEUROD6 | c.240G>T p.R80S | Missense Mutation (SNP) | VAF 121/408 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV51769940, COSV51773190; called by muse, mutect2, varscan2
- NUMA1 | c.6289G>A p.A2097T | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs371005806; called by muse, mutect2, varscan2
- PCDH10 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV52105832; called by muse, mutect2, varscan2
- PCDHGB6 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 110/388 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1477022032, COSV53961691; called by muse, mutect2, varscan2
- PDZD4 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 226/226 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs782409938, COSV51246022; called by muse, mutect2, varscan2
- PRKAR1B | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 114/304 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs748743633; called by muse, mutect2, varscan2
- PRR23A | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 232/394 reads (59%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as COSV101270282, COSV67213484; called by muse, mutect2, varscan2
- RAB35 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 100/390 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs895224371; called by muse, mutect2, varscan2
- RBMXL3 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 355/356 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.492); catalogued as COSV57747518; called by muse, mutect2, varscan2
- SIGLEC9 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs759377738, COSV51583448; called by muse, varscan2
- SLC38A4 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs759965383; called by muse, mutect2, varscan2
- SLC4A3 | c.1462-8G>A | Splice Region (SNP) | VAF 58/194 reads (30%) | catalogued as rs757584414; called by muse, mutect2, varscan2
- SOS2 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1364027643, COSV53567356; called by muse, mutect2, varscan2
- SOX30 | c.1982G>T p.G661V (on ENST00000265007 / NM_178424.2; = p.V497L on NM_007017.2) | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs771440810; called by muse, mutect2, varscan2
- SYT16 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs758851790, COSV70858745; called by muse, mutect2, varscan2
- TECTA | c.4207G>A p.V1403M | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200563210, COSV50754454; called by muse, mutect2, varscan2
- TEKT4 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352998128, COSV54623712; called by muse, mutect2, varscan2
- TEX9 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775480026, COSV61878648; called by muse, mutect2, varscan2
- TMEM151A | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 109/109 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs752400796, COSV59173625; called by muse, mutect2, varscan2
- TMPRSS15 | c.2999G>A p.R1000H | Missense Mutation (SNP) | VAF 385/387 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as rs192022515, COSV53040788; called by muse, mutect2, varscan2
- TNRC6C | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 68/68 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs978647209, COSV56948343; called by muse, mutect2, varscan2
- TSGA10IP | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs759743147; called by muse, mutect2, varscan2
- ZER1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs754228946; called by muse, mutect2, varscan2
- ZFC3H1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 121/366 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1196788792; called by muse, mutect2, varscan2
- ZMIZ2 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs753507016; called by muse, mutect2, varscan2
- ZNF175 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 213/213 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs772936588, COSV51798930; called by muse, mutect2, varscan2
- ZNF497 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs527968162; called by muse, mutect2, varscan2
- ZNF536 | c.3686C>T p.P1229L | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs371124100; called by muse, mutect2, varscan2
- ZNF585A | c.1918G>A p.G640R (on ENST00000292841 / NM_001288800.2; = p.G585R on NM_152655.3) | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs189237393; called by muse, mutect2, varscan2
- ABCC11 | c.1653C>A p.S551R | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AFF2 | c.2627C>A p.T876N | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- AMER1 | c.1169del p.L390* | Frame Shift Del (DEL) | VAF 174/240 reads (73%) | called by mutect2, pindel, varscan2
- APC | c.4546del p.I1516Yfs*7 | Frame Shift Del (DEL) | VAF 94/217 reads (43%) | called by mutect2, pindel, varscan2
- BIRC6 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 227/376 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAPRIN2 | c.2806C>T p.P936S | Missense Mutation (SNP) | VAF 119/380 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC20B | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 97/339 reads (29%) | called by muse, mutect2
- CFTR | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 89/390 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRAT | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 178/261 reads (68%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- CSMD1 | c.9697G>A p.G3233S (on ENST00000520002; = p.G3232S on NM_033225.6) | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP4V2 | c.1380_1382delinsTT p.S461Lfs*8 | Frame Shift Del (DEL) | VAF 75/332 reads (23%) | called by pindel, varscan2*
- DDX54 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 242/416 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAT4 | c.14351C>A p.S4784Y | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- FLG2 | c.3542A>G p.Q1181R | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- HK3 | c.2054-6C>A | Splice Region (SNP) | VAF 56/149 reads (38%) | called by muse, mutect2, varscan2
- HMCN1 | c.6138G>T p.L2046F | Missense Mutation (SNP) | VAF 188/880 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HNRNPL | c.1552_1554del p.F518del | In Frame Del (DEL) | VAF 24/35 reads (69%) | called by mutect2, pindel, varscan2
- IGHV2-26 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 97/335 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KCNC1 | c.1311C>G p.N437K | Missense Mutation (SNP) | VAF 294/294 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNH5 | c.1660G>T p.A554S | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- KIAA1109 | c.11803A>T p.K3935* | Nonsense Mutation (SNP) | VAF 122/223 reads (55%) | called by muse, mutect2, varscan2
- LNX1 | c.2058_2061dup p.I688* (on ENST00000263925 / NM_001126328.3; = p.I592* on NM_032622.2) | Nonsense Mutation (INS) | VAF 40/114 reads (35%) | called by mutect2, pindel
- MAP6 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MC3R | c.930del p.F310Lfs*11 | Frame Shift Del (DEL) | VAF 136/1192 reads (11%) | called by mutect2, pindel, varscan2
- MOCS1 | c.905G>T p.S302I | Missense Mutation (SNP) | VAF 251/251 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NPAS4 | c.1133C>G p.A378G | Missense Mutation (SNP) | VAF 138/138 reads (100%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- NT5C1B | c.732G>T p.K244N (on ENST00000359846 / NM_001199086.2; = p.K184N on NM_033253.4) | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); called by muse, varscan2
- OCA2 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 165/277 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR5K1 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 102/298 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OS9 | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PDE10A | c.1434C>A p.D478E | Missense Mutation (SNP) | VAF 139/140 reads (99%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PRAMEF10 | c.525A>T p.R175S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by mutect2, varscan2
- PRICKLE1 | c.1979T>C p.V660A | Missense Mutation (SNP) | VAF 127/370 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTN | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 86/470 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRF | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RFPL2 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 60/60 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- SH3RF2 | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SIL1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 81/264 reads (31%) | called by mutect2, varscan2
- SIVA1 | c.16T>G p.C6G | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SLC26A2 | c.1805_1808del p.Q602Lfs*6 | Frame Shift Del (DEL) | VAF 71/271 reads (26%) | called by pindel, varscan2
- SLK | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 203/204 reads (100%) | called by muse, mutect2, varscan2
- TAP2 | c.2047C>A p.L683I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TTLL3 | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TUB | c.1105G>A p.A369T (on ENST00000299506 / NM_177972.3; = p.A424T on NM_003320.4) | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VCX3B | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 107/709 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); called by muse, varscan2
- VTCN1 | c.619_620del p.T207Hfs*21 | Frame Shift Del (DEL) | VAF 72/171 reads (42%) | called by mutect2, pindel, varscan2
- ADCYAP1R1 | c.585G>A p.S195= | Silent (SNP) | VAF 73/117 reads (62%) | catalogued as rs1184308352, COSV58446469, COSV58446644; called by muse, mutect2, varscan2
- AKAP6 | c.6195C>T p.D2065= | Silent (SNP) | VAF 53/89 reads (60%) | catalogued as rs771087787; called by muse, mutect2, varscan2
- ARL3 | c.507C>A p.G169= | Silent (SNP) | VAF 132/132 reads (100%) | catalogued as COSV53299689; called by muse, mutect2, varscan2
- CAVIN1 | c.1101C>T p.P367= | Silent (SNP) | VAF 87/87 reads (100%) | catalogued as rs1225721187; called by muse, mutect2, varscan2
- CCR6 | c.33T>C p.V11= | Silent (SNP) | VAF 55/55 reads (100%) | called by muse, mutect2, varscan2
- CD48 | c.448C>T p.L150= | Silent (SNP) | VAF 279/279 reads (100%) | catalogued as rs17851383; called by muse, mutect2, varscan2
- CMYA5 | c.285T>A p.P95= | Silent (SNP) | VAF 48/161 reads (30%) | called by muse, mutect2, varscan2
- COL16A1 | c.1446G>A p.S482= | Silent (SNP) | VAF 130/130 reads (100%) | catalogued as rs747289524; called by muse, mutect2, varscan2
- DENND1A | c.1260G>A p.K420= | Silent (SNP) | VAF 75/141 reads (53%) | catalogued as COSV101010409; called by muse, mutect2, varscan2
- DMD | c.162C>T p.L54= | Silent (SNP) | VAF 234/234 reads (100%) | catalogued as rs904011265, CD100307, COSV55876706; ClinVar: likely benign; called by muse, mutect2, varscan2
- ERICH3 | c.3498G>A p.S1166= | Silent (SNP) | VAF 53/103 reads (51%) | catalogued as rs200380141, COSV58616297; called by muse, mutect2, varscan2
- FBN3 | c.2301C>T p.V767= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1414194461, COSV54468088; called by muse, mutect2
- GATAD1 | c.280C>A p.R94= | Silent (SNP) | VAF 102/352 reads (29%) | called by muse, mutect2, varscan2
- H2BC12 | c.252C>T p.Y84= | Silent (SNP) | VAF 419/436 reads (96%) | catalogued as rs1475848743; called by muse, mutect2, varscan2
- HAS1 | c.1638C>A p.G546= | Silent (SNP) | VAF 67/115 reads (58%) | called by muse, mutect2, varscan2
- ILF3 | c.795G>A p.P265= | Silent (SNP) | VAF 223/223 reads (100%) | catalogued as rs759971222, COSV51561817; called by muse, mutect2, varscan2
- IRS1 | c.2163C>T p.S721= | Silent (SNP) | VAF 209/336 reads (62%) | catalogued as rs753351880; called by muse, mutect2, varscan2
- KDM4D | c.699C>A p.G233= | Silent (SNP) | VAF 136/439 reads (31%) | called by muse, mutect2, varscan2
- MRGPRX4 | c.249G>A p.L83= | Silent (SNP) | VAF 78/239 reads (33%) | catalogued as rs1163488143; called by muse, mutect2, varscan2
- MTA1 | c.1251C>T p.C417= | Silent (SNP) | VAF 53/163 reads (33%) | catalogued as rs139203829; called by muse, mutect2, varscan2
- NFKB1 | c.2259C>G p.L753= (on ENST00000394820 / NM_001382627.1; = p.L754= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 51/156 reads (33%) | called by muse, mutect2, varscan2
- OR2T34 | c.204C>A p.I68= | Silent (SNP) | VAF 161/201 reads (80%) | called by mutect2, varscan2
- PCDHB10 | c.2163G>A p.A721= | Silent (SNP) | VAF 120/363 reads (33%) | catalogued as rs1554284475; called by muse, mutect2, varscan2
- PLAG1 | c.528G>A p.S176= | Silent (SNP) | VAF 100/371 reads (27%) | catalogued as rs374803048; called by muse, mutect2, varscan2
- PLPP7 | c.312G>A p.A104= | Silent (SNP) | VAF 93/162 reads (57%) | catalogued as rs371251864; called by muse, mutect2, varscan2
- PLXNB3 | c.1731C>T p.H577= | Silent (SNP) | VAF 138/210 reads (66%) | catalogued as rs782548296, COSV62800826; called by muse, mutect2, varscan2
- PRSS1 | c.360C>T p.N120= | Silent (SNP) | VAF 496/663 reads (75%) | catalogued as rs606231348; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- SERPINE3 | c.786G>T p.L262= | Silent (SNP) | VAF 328/550 reads (60%) | called by muse, mutect2, varscan2
- SOX3 | c.165T>A p.A55= | Silent (SNP) | VAF 135/135 reads (100%) | called by muse, mutect2, varscan2
- SPANXN2 | c.507A>G p.S169= | Silent (SNP) | VAF 198/294 reads (67%) | called by muse, varscan2
- SSH3 | c.1050G>T p.L350= | Silent (SNP) | VAF 139/213 reads (65%) | called by muse, mutect2, varscan2
- TES | c.285G>A p.T95= | Silent (SNP) | VAF 254/337 reads (75%) | catalogued as rs756663029, COSV64041709; called by muse, mutect2, varscan2
- TMEM132D | c.171C>T p.D57= | Silent (SNP) | VAF 100/339 reads (29%) | catalogued as rs200983727; called by muse, mutect2, varscan2
- TMEM266 | c.801G>A p.A267= | Silent (SNP) | VAF 110/172 reads (64%) | called by muse, mutect2, varscan2
- TRIM71 | c.567G>A p.S189= | Silent (SNP) | VAF 90/303 reads (30%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.3210G>A p.V1070= | Silent (SNP) | VAF 106/274 reads (39%) | called by muse, mutect2, varscan2
- UGT3A2 | c.1149G>T p.V383= | Silent (SNP) | VAF 72/118 reads (61%) | called by muse, mutect2, varscan2
- ZNF229 | c.447G>A p.P149= | Silent (SNP) | VAF 116/186 reads (62%) | catalogued as rs190811456; called by muse, mutect2, varscan2
- ZNF783 | c.435C>T p.F145= | Silent (SNP) | VAF 101/473 reads (21%) | catalogued as rs368656431; called by muse, mutect2, varscan2
- A2M | c.4409-17dup | Intron (INS) | VAF 40/174 reads (23%) | catalogued as rs749161826; called by mutect2, varscan2
- AC093791.1 | n.471A>T | RNA (SNP) | VAF 51/169 reads (30%) | called by muse, mutect2, varscan2
- AP003062.1 | n.878G>T | RNA (SNP) | VAF 185/768 reads (24%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2505C>A | 3'UTR (SNP) | VAF 54/174 reads (31%) | called by muse, mutect2, varscan2
- GMFB | c.-41G>A | 5'UTR (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- HNRNPA3P1 | n.415G>C | RNA (SNP) | VAF 152/152 reads (100%) | called by muse, varscan2
- HNRNPA3P1 | n.386T>C | RNA (SNP) | VAF 111/111 reads (100%) | catalogued as rs778904809; called by muse, varscan2
- MLF2 | c.399+14C>T | Intron (SNP) | VAF 96/139 reads (69%) | called by muse, mutect2, varscan2
- PLBD2 | chr12:113358580 del G | 5'Flank (DEL) | VAF 92/319 reads (29%) | catalogued as rs771064415; called by mutect2, pindel, varscan2
- SQSTM1 | c.-2C>G | 5'UTR (SNP) | VAF 79/116 reads (68%) | catalogued as COSV100657618, COSV62435005; called by muse, mutect2, varscan2
- TTLL9 | c.*71G>A | 3'UTR (SNP) | VAF 169/479 reads (35%) | catalogued as rs774430370; called by muse, mutect2, varscan2
- UTS2B | c.334+1695A>G | Intron (SNP) | VAF 54/197 reads (27%) | called by muse, mutect2, varscan2
- WASF4P | n.1234C>T | RNA (SNP) | VAF 86/86 reads (100%) | called by muse, mutect2, varscan2
- ZNF829 | c.-85+71C>A | Intron (SNP) | VAF 35/123 reads (28%) | called by muse, mutect2, varscan2
